Somatic mutation profile of tumor specimen TCGA-56-7731-01A (aliquot TCGA-56-7731-01A-11D-2122-08) from TCGA case TCGA-56-7731, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.9 years (24,441 days).
Specimen TCGA-56-7731-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d7ad3f27-7a9f-4648-aeee-928991919568.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-7731-10A (Blood Derived Normal), aliquot TCGA-56-7731-10A-01D-2122-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1223f70-c2d2-4349-ac42-097e98e73fa5

The open-access MAF lists 344 somatic variants for this specimen: 258 protein-altering or splice-affecting, 77 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 226, Silent 77, Nonsense Mutation 19, Splice Site 7, Frame Shift Del 4, Intron 4, RNA 4, Frame Shift Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 6/15 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AARS2 | c.1931A>T p.Q644L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.055); catalogued as COSV99771770; called by muse, mutect2
- ABCD1 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.215); catalogued as COSV54384008, COSV99497984; called by muse, mutect2
- AC008397.2 | c.1558G>T p.V520L | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99442433; called by muse, mutect2, varscan2
- AC013489.1 | c.743G>C p.G248A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV51552975, COSV99183917; called by muse, mutect2, varscan2
- ACE2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99383218; called by muse, mutect2
- ADAM23 | c.1793G>T p.R598L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV100009148; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2630T>C p.M877T | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV99721818; called by muse, mutect2, varscan2
- ADGRE1 | c.1970A>G p.H657R | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99166028; called by muse, mutect2
- ADGRL3 | c.1001C>A p.A334E (on ENST00000506720 / NM_001322402.2; = p.A266E on NM_015236.6) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101547447; called by muse, mutect2, varscan2
- ADGRL4 | c.176A>G p.D59G | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV100876624; called by muse, mutect2
- AFDN | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs1166578643, COSV100652880, COSV100653760; called by muse, mutect2
- AKAP9 | c.7502T>G p.L2501R (on ENST00000359028; = p.L2477R on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV100663357; called by muse, mutect2, varscan2
- ANO5 | c.2248G>C p.A750P | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100202371; called by muse, mutect2
- APOB | c.12575C>A p.S4192* | Nonsense Mutation (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99268703; called by muse, mutect2
- ARHGAP11A | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100853390; called by muse, mutect2, varscan2
- ATG2B | c.4119C>A p.N1373K | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV99952287; called by muse, mutect2, varscan2
- AVPR1B | c.670C>A p.H224N | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.356); catalogued as COSV100899485; called by muse, mutect2
- BTK | c.185C>T p.T62I | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100438045; called by muse, mutect2
- C12orf40 | c.1572G>A p.M524I | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV61129563; called by muse, mutect2, varscan2
- CANX | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs901153010, COSV99910743; called by muse, mutect2, varscan2
- CAPN6 | c.1200G>T p.M400I | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100137154; called by muse, mutect2, varscan2
- CARD6 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54565807, COSV99621451; called by muse, mutect2, varscan2
- CAVIN4 | c.47A>T p.N16I | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV100293454; called by muse, mutect2, varscan2
- CBLL2 | c.79G>T p.V27L | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100081807; called by muse, mutect2, varscan2
- CD163 | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100776203; called by muse, mutect2
- CD40 | c.498-1G>T p.X166_splice | Splice Site (SNP) | VAF 8/97 reads (8%) | catalogued as COSV100953888; called by muse, mutect2
- CDC40 | c.568G>C p.D190H | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV100309618; called by muse, mutect2
- CDK8 | c.1238C>T p.S413L | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV67421475; called by muse, mutect2
- CFAP45 | c.662T>A p.L221Q | Missense Mutation (SNP) | VAF 34/322 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100928692; called by muse, mutect2
- CHD7 | c.8584G>C p.D2862H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as COSV101418586; called by muse, mutect2
- CHST4 | c.187G>T p.G63W | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100632980; called by muse, mutect2, varscan2
- CLCN1 | c.2938G>T p.E980* | Nonsense Mutation (SNP) | VAF 11/127 reads (9%) | catalogued as COSV100578683, COSV58370073; called by muse, mutect2
- CLSTN2 | c.1029G>T p.W343C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV101515950; called by muse, mutect2, varscan2
- CNGA2 | c.1305G>C p.K435N | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100324008; called by muse, mutect2, varscan2
- CNTNAP2 | c.3016G>T p.G1006C | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100661636; called by muse, mutect2
- COL12A1 | c.1810G>T p.A604S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV100486805; called by muse, mutect2, varscan2
- COL24A1 | c.2383G>A p.G795R | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100994194; called by muse, mutect2, varscan2
- COL4A6 | c.3836C>A p.P1279Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.1); catalogued as COSV100565226; called by muse, mutect2, varscan2
- CPXM2 | c.653+1G>T p.X218_splice | Splice Site (SNP) | VAF 15/112 reads (13%) | catalogued as COSV99583604; called by muse, mutect2, varscan2
- CTNNA1 | c.848A>G p.N283S | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as rs750584026, COSV100243351; called by muse, mutect2, varscan2
- DCAF4L2 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100151407; called by muse, mutect2, varscan2
- DEPDC5 | c.3460G>A p.G1154S (on ENST00000400246; = p.G1223S on NM_014662.5) | Missense Mutation (SNP) | VAF 25/258 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746114133, COSV99836875; called by muse, mutect2
- DIS3 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100900038, COSV66706033; called by muse, mutect2, varscan2
- DMD | c.5411G>C p.G1804A | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.171); catalogued as COSV104419533, COSV63797436; called by muse, mutect2
- DNAH3 | c.8743C>A p.L2915M | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99771364; called by muse, mutect2, varscan2
- DNAH8 | c.9489T>C p.N3163= | Splice Region (SNP) | VAF 4/21 reads (19%) | catalogued as COSV100547467; called by muse, mutect2
- DNAH8 | c.10587A>T p.L3529F | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100547468; called by muse, mutect2
- DNASE1L1 | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.109); catalogued as COSV99186450; called by muse, mutect2
- DOP1A | c.5186C>T p.A1729V | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99383174; called by muse, mutect2
- DPH2 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99356706; called by muse, mutect2
- DPP4 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as COSV100859164; called by muse, mutect2
- DPY19L3 | c.1853G>T p.R618M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100639340; called by muse, mutect2, varscan2
- DRC7 | c.1337T>C p.L446P | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100395958; called by muse, mutect2
- DRC7 | c.1576G>T p.V526F | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV100395960; called by muse, mutect2
- DROSHA | c.838A>T p.S280C | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100757864; called by muse, mutect2
- DSC1 | c.1961T>C p.L654S | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as rs1289438274, COSV99938420; called by muse, mutect2
- DST | c.11062G>A p.E3688K (on ENST00000361203 / NM_001374722.1; = p.E1276K on NM_015548.5) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs1435348308, COSV99761053; called by muse, mutect2
- DYNC2H1 | c.9754A>G p.I3252V | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV100520025; called by muse, mutect2, varscan2
- ECEL1 | c.1721A>G p.Y574C | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370641510; called by muse, mutect2, varscan2
- EFR3A | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.043); catalogued as COSV54459923, COSV99603758; called by muse, mutect2, varscan2
- EIF2AK3 | c.2461G>T p.E821* | Nonsense Mutation (SNP) | VAF 10/120 reads (8%) | catalogued as COSV100304248; called by muse, mutect2
- EML1 | c.396G>T p.R132S | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV99215813; called by muse, mutect2, varscan2
- EPHA8 | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99385929; called by muse, mutect2
- EPO | c.509G>T p.R170L | Missense Mutation (SNP) | VAF 16/174 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.37); catalogued as COSV53162309, COSV99402695; called by muse, mutect2, varscan2
- FAHD2B | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99738346; called by muse, mutect2, varscan2
- FAM71A | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as COSV99674973; called by muse, mutect2, varscan2
- FASTK | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs377740282; called by mutect2, varscan2
- FAT1 | c.3535A>T p.T1179S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as rs200917026, COSV101499698; called by mutect2, varscan2
- FAT2 | c.11906-2A>G p.X3969_splice | Splice Site (SNP) | VAF 10/98 reads (10%) | catalogued as rs925187682, COSV99944501; called by muse, mutect2
- FBXL7 | c.1148C>A p.A383E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100311181, COSV61647642; called by muse, mutect2
- FCRL1 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.732); catalogued as rs756516538, COSV100839699, COSV63823726; called by muse, varscan2
- FGF16 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV101466331; called by muse, mutect2
- FH | c.296T>A p.L99* | Nonsense Mutation (SNP) | VAF 8/128 reads (6%) | catalogued as COSV100845104; called by muse, mutect2
- FLNA | c.2268C>A p.N756K | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as COSV100774643; called by muse, mutect2
- FSCB | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100470024; called by muse, mutect2, varscan2
- GABRA1 | c.226A>T p.S76C | Missense Mutation (SNP) | VAF 28/175 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99196366; called by muse, mutect2, varscan2
- GABRA2 | c.1096G>T p.A366S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.069); catalogued as COSV100734845; called by muse, mutect2, varscan2
- GALNT13 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as COSV101224411; called by muse, mutect2, varscan2
- GCOM1 | c.556A>T p.S186C | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV99985431; called by muse, mutect2, varscan2
- GDNF | c.158T>C p.M53T | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1561126379, COSV100427607; called by muse, mutect2, varscan2
- GPC5 | c.1255T>C p.W419R | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100996360; called by muse, mutect2
- GPI | c.1372G>T p.D458Y | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100731607; called by muse, mutect2, varscan2
- GPR1 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV101329878; called by muse, mutect2, varscan2
- GPRASP2 | c.1352C>A p.S451Y | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV100176554, COSV59991083; called by muse, mutect2
- GTF2IRD1 | c.2043G>T p.E681D (on ENST00000265755 / NM_016328.3; = p.E666D on NM_005685.4) | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV99735840; called by muse, mutect2
- GUCY1B1 | c.130G>T p.D44Y | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100026022; called by muse, mutect2
- HCFC1 | c.2584G>A p.V862I | Missense Mutation (SNP) | VAF 12/109 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.959); catalogued as rs1057524502, COSV100130176; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDAC6 | c.3455A>T p.Y1152F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.014); catalogued as COSV100491364; called by mutect2, varscan2
- HDHD5 | c.389A>G p.H130R (on ENST00000336737 / NM_033070.3; = p.H100R on NM_017829.5) | Missense Mutation (SNP) | VAF 52/393 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1168424600, COSV50092253; called by muse, mutect2, varscan2
- HSPD1 | c.1706G>T p.G569V | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as COSV100798437; called by muse, mutect2, varscan2
- IFI44 | c.178A>G p.I60V | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.014); catalogued as COSV100877447; called by muse, mutect2, varscan2
- IGKV1-9 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.541); catalogued as rs563474094; called by muse, mutect2
- IL4R | c.594G>T p.R198S | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as COSV99405478; called by muse, mutect2
- ING2 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as COSV100180514; called by muse, mutect2, varscan2
- ISL2 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99320947; called by muse, mutect2
- ISM2 | c.1243C>A p.L415I | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99376961; called by muse, mutect2, varscan2
- JAK1 | c.2286G>T p.E762D | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100692605; called by muse, mutect2
- KIF21A | c.3622G>T p.E1208* (on ENST00000361418 / NM_001378440.1; = p.E1195* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/126 reads (6%) | catalogued as COSV100735775; called by muse, mutect2
- KIZ | c.859A>T p.R287* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV99852494; called by muse, mutect2, varscan2
- KRT2 | c.943G>T p.V315F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV100548709; called by muse, mutect2, varscan2
- LAMA2 | c.1331G>A p.C444Y | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101370947; called by muse, mutect2, varscan2
- LARGE1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1043459846, COSV100506620; called by muse, mutect2, varscan2
- LDB2 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100455205; called by muse, mutect2, varscan2
- LILRA1 | c.788G>T p.R263L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.169); catalogued as COSV99252326; called by muse, mutect2
- LILRB5 | c.1504G>C p.G502R (on ENST00000449561 / NM_001081442.3; = p.G501R on NM_006840.5) | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100300936; called by muse, mutect2, varscan2
- LUZP4 | c.378G>T p.E126D | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.765); catalogued as rs782380133, COSV100904889; called by muse, mutect2, varscan2
- MACF1 | c.2147C>T p.S716L | Missense Mutation (SNP) | VAF 13/116 reads (11%) | catalogued as rs1313628095, COSV100487118; called by muse, mutect2, varscan2
- MAGEA10 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99726966; called by muse, mutect2, varscan2
- MAGEE1 | c.1915G>T p.D639Y | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100819557; called by muse, mutect2
- MAOB | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV100955858, COSV100956289; called by muse, mutect2
- MAP3K15 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100136048; called by muse, mutect2, varscan2
- MDGA2 | c.2895A>T p.E965D (on ENST00000399232 / NM_001113498.2; = p.E667D on NM_182830.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100638861; called by muse, mutect2, varscan2
- MID1 | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 14/153 reads (9%) | catalogued as COSV100452810, COSV100452811; called by muse, mutect2
- MID2 | c.2112G>C p.L704F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99465861; called by muse, mutect2, varscan2
- MORN3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs782764590, COSV62506994; called by muse, mutect2
- MRPS16 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100161161; called by muse, mutect2
- MS4A14 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs868515461, COSV100280791; called by muse, mutect2, varscan2
- MTM1 | c.867+2T>C p.X289_splice | Splice Site (SNP) | VAF 9/95 reads (9%) | catalogued as CS001837, COSV100080783; called by muse, mutect2
- MTRR | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as COSV99242203; called by muse, mutect2, varscan2
- MUC16 | c.34247G>C p.S11416T | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.206); catalogued as COSV101202188; called by muse, mutect2, varscan2
- MUC16 | c.25688C>A p.S8563Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); catalogued as COSV67476289; called by muse, mutect2, varscan2
- MUC16 | c.2926A>G p.T976A | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV101202191; called by muse, mutect2
- MYF6 | c.586G>T p.G196W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.161); catalogued as COSV99952991; called by muse, mutect2, varscan2
- MYH15 | c.3721G>C p.D1241H | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99844564; called by muse, mutect2, varscan2
- MYO1A | c.2395A>G p.N799D | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs1004026421, COSV100271352; called by muse, mutect2, varscan2
- MYT1 | c.1246G>T p.A416S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV100115729; called by muse, mutect2
- NAALADL2 | c.755G>T p.R252I | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); catalogued as COSV101458199; called by muse, mutect2, varscan2
- NECTIN3 | c.467G>T p.G156V | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100162828; called by muse, mutect2
- NELL1 | c.913C>T p.R305* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs942786957, COSV100126029; called by muse, mutect2, varscan2
- NEU4 | c.988C>T p.P330S (on ENST00000391969 / NM_001167602.3; = p.P342S on NM_080741.4) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100372242; called by muse, mutect2
- NLRP13 | c.3104C>A p.S1035* | Nonsense Mutation (SNP) | VAF 18/240 reads (8%) | catalogued as COSV100738637, COSV61621599; called by muse, mutect2
- NLRP7 | c.2644T>A p.L882I (on ENST00000340844 / NM_206828.3; = p.L854I on NM_139176.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100053497; called by muse, mutect2
- NLRP7 | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.538); catalogued as COSV60180570; called by muse, mutect2, varscan2
- NPHS1 | c.2072-1G>T p.X691_splice | Splice Site (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100800365; called by muse, mutect2, varscan2
- NRAP | c.1205T>C p.F402S | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV100748672; called by muse, mutect2
- NRXN3 | c.1468A>T p.K490* (on ENST00000335750 / NM_001330195.2; = p.K117* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 9/121 reads (7%) | catalogued as COSV100210743; called by muse, mutect2
- NSFL1C | c.944G>C p.S315T | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99401695; called by muse, mutect2, varscan2
- NXPE4 | c.1170C>A p.N390K (on ENST00000375478 / NM_001077639.2; = p.N106K on NM_017678.3) | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV100970598; called by muse, mutect2
- OR10Q1 | c.697A>T p.I233F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV100372432; called by muse, mutect2, varscan2
- OR2A12 | c.742G>T p.G248W | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283213; called by muse, mutect2
- OR2T4 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 26/267 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63543758, COSV63544321; called by muse, mutect2
- OR3A3 | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99351611; called by muse, mutect2, varscan2
- OR4K15 | c.408G>C p.M136I (on ENST00000305051; = p.M112I on NM_001005486.1) | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV100521191; called by muse, mutect2
- OR4K5 | c.94T>A p.S32T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV100262685; called by muse, mutect2, varscan2
- OR51L1 | c.423T>A p.S141R | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100386515; called by muse, mutect2, varscan2
- OR56A3 | c.866C>G p.A289G | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100290405; called by muse, mutect2, varscan2
- OR5AN1 | c.631A>T p.S211C | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV100004507; called by muse, mutect2
- OR5D16 | c.637C>A p.L213I | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.597); catalogued as COSV65722237; called by muse, mutect2
- OR5H14 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 68/333 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV101454341; called by muse, mutect2, varscan2
- OR5H6 | c.220C>G p.P74A (on ENST00000642105; = p.P58A on NM_001005479.2) | Missense Mutation (SNP) | VAF 23/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV101051831, COSV67351873; called by muse, mutect2
- OR5T1 | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100479279; called by muse, mutect2, varscan2
- OVGP1 | c.1108G>T p.G370C | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100868291; called by muse, mutect2
- P2RY10 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99409474; called by muse, mutect2, varscan2
- PAPPA2 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as rs1457024064, COSV100867272; called by muse, mutect2, varscan2
- PAPPA2 | c.3513G>T p.E1171D | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as rs773924568, COSV100867580, COSV100868812; called by muse, mutect2
- PCDH11X | c.3862G>T p.G1288W | Missense Mutation (SNP) | VAF 28/378 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV53485723; called by muse, mutect2
- PCDHA5 | c.2123G>T p.S708I | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100972633; called by muse, mutect2, varscan2
- PCDHA7 | c.1411G>T p.G471C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100971970, COSV65342786; called by muse, mutect2, varscan2
- PCDHB16 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99502171, COSV99503154; called by muse, mutect2, varscan2
- PCDHGB1 | c.544A>T p.S182C | Missense Mutation (SNP) | VAF 31/204 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.926); catalogued as COSV99549346; called by muse, mutect2, varscan2
- PHF24 | c.142G>C p.V48L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs757000601, COSV99646359; called by muse, mutect2, varscan2
- PITRM1 | c.1210G>T p.V404F | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs773535745, COSV56531386; called by muse, mutect2, varscan2
- PKD1L1 | c.4833G>T p.R1611S | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.681); catalogued as COSV99221747; called by muse, mutect2, varscan2
- PKD1L1 | c.3008C>A p.S1003* | Nonsense Mutation (SNP) | VAF 17/105 reads (16%) | catalogued as COSV99221750; called by muse, mutect2, varscan2
- PKHD1 | c.5645G>T p.C1882F | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100584954; called by muse, mutect2
- PLAC1 | c.190A>T p.N64Y | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100821685; called by muse, mutect2
- PLG | c.1535G>A p.R512K | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99805270; called by muse, mutect2
- PNMA5 | c.679T>G p.C227G | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100721735; called by muse, mutect2
- PPP1R16B | c.1603G>A p.V535I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV100240231; called by muse, mutect2, varscan2
- PRDX6 | c.542G>A p.W181* | Nonsense Mutation (SNP) | VAF 10/171 reads (6%) | catalogued as COSV100458596; called by muse, mutect2
- PTH1R | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.253); catalogued as COSV100481218; called by muse, mutect2, varscan2
- RABGAP1L | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99275199; called by muse, mutect2, varscan2
- RAD54L2 | c.4231C>T p.R1411W | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.466); catalogued as rs747266400, COSV56578426; called by muse, mutect2, varscan2
- RBM46 | c.1543G>C p.A515P | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.401); catalogued as COSV55980918, COSV99908515; called by muse, mutect2, varscan2
- RCN1 | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277518; called by muse, mutect2
- RGN | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100282573; called by muse, mutect2
- RIMS2 | c.1004G>A p.S335N (on ENST00000666250 / NM_001348490.2; = p.S143N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs773044369, COSV99212692; called by muse, mutect2, varscan2
- RIT2 | c.310C>A p.R104S | Missense Mutation (SNP) | VAF 24/339 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs962872061, COSV56306575, COSV99951308; called by muse, mutect2
- RNF10 | c.1919A>G p.Q640R | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.145); catalogued as COSV100379084; called by muse, mutect2
- ROCK2 | c.1693G>T p.D565Y | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV99838027; called by muse, mutect2
- RPS6KA6 | c.1804G>C p.A602P | Missense Mutation (SNP) | VAF 18/271 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99425632; called by muse, mutect2
- RTL4 | c.23C>G p.S8* | Nonsense Mutation (SNP) | VAF 17/131 reads (13%) | catalogued as COSV100466204, COSV61205685; called by muse, mutect2, varscan2
- RTL9 | c.2398G>T p.A800S | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV101511821; called by muse, mutect2, varscan2
- RUNX2 | c.740G>T p.S247I | Missense Mutation (SNP) | VAF 19/257 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100767947; called by muse, mutect2
- S100A7 | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV100906767; called by muse, mutect2, varscan2
- SAMD9L | c.2576A>T p.Y859F | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.202); catalogued as COSV100561228; called by muse, mutect2
- SCYL2 | c.856A>T p.S286C | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV100675332; called by muse, mutect2
- SDCBP | c.199C>A p.R67S | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV99486582; called by muse, mutect2, varscan2
- SEMA4D | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.16); catalogued as COSV100358948; called by muse, mutect2
- SHLD1 | c.302G>T p.R101I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.289); catalogued as COSV100290778; called by muse, mutect2
- SIGLEC1 | c.2677G>T p.V893F | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99171503; called by muse, mutect2, varscan2
- SLC37A1 | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV100721872; called by muse, mutect2, varscan2
- SLC6A4 | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 7/136 reads (5%) | catalogued as COSV99911655; called by muse, mutect2
- SLFN11 | c.889C>G p.L297V | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV100391117; called by muse, mutect2
- SNAP91 | c.250C>A p.H84N | Missense Mutation (SNP) | VAF 26/272 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99536991; called by muse, mutect2
- SNTG2 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138780480; called by muse, mutect2, varscan2
- SP140 | c.2045C>A p.S682* | Nonsense Mutation (SNP) | VAF 6/88 reads (7%) | catalogued as COSV100614169; called by muse, mutect2
- SPAG16 | c.1780G>C p.G594R | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100436495, COSV56968443; called by muse, mutect2, varscan2
- SPOPL | c.176C>G p.S59C | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as COSV99699886; called by muse, mutect2
- SULF1 | c.1319G>A p.R440Q | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1034336118; called by muse, mutect2, varscan2
- TAGAP | c.1722C>A p.H574Q | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV100487681, COSV100487696; called by muse, mutect2
- TBC1D8B | c.2595G>A p.W865* | Nonsense Mutation (SNP) | VAF 18/138 reads (13%) | catalogued as COSV99345201; called by muse, mutect2, varscan2
- TBXA2R | c.265C>G p.H89D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100916151, COSV100916348; called by muse, mutect2
- TCIRG1 | c.2176G>T p.G726C | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99693717; called by muse, mutect2
- TEC | c.595A>T p.R199* | Nonsense Mutation (SNP) | VAF 12/156 reads (8%) | catalogued as COSV101202707; called by muse, mutect2
- TECRL | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 20/188 reads (11%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs772552417, COSV101169535; called by muse, mutect2
- TENM1 | c.559C>T p.Q187* | Nonsense Mutation (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100951280; called by muse, mutect2, varscan2
- TFRC | c.2213C>G p.A738G | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV100786654; called by muse, mutect2
- THBS2 | c.2239G>C p.D747H | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100828155; called by muse, mutect2
- THRAP3 | c.1996G>T p.A666S | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.171); catalogued as COSV100663693; called by muse, mutect2
- TLR8 | c.909T>A p.N303K (on ENST00000218032 / NM_138636.5; = p.N321K on NM_016610.4) | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV99487391; called by muse, mutect2
- TMEM200A | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.142); catalogued as COSV99760274; called by muse, mutect2
- TMEM200A | c.557C>A p.T186N | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99760275; called by muse, mutect2, varscan2
- TMEM214 | c.1987G>T p.A663S | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.492); catalogued as COSV99476595; called by muse, mutect2, varscan2
- TRIM49 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.062); catalogued as rs906647817, COSV100316285; called by muse, mutect2
- TRPA1 | c.2806C>G p.L936V | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100085526, COSV51555219; called by muse, mutect2
- TRPC3 | c.1592T>A p.L531Q (on ENST00000379645 / NM_001366479.2; = p.L458Q on NM_003305.2) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.296); catalogued as COSV99313681; called by muse, mutect2
- TRPM1 | c.2106G>T p.E702D | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99856937; called by muse, mutect2, varscan2
- TSPYL2 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.227); catalogued as rs377693568, COSV100966392; called by muse, mutect2
- TTI1 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756725781, COSV100989795, COSV65062660; called by muse, mutect2, varscan2
- TTK | c.1745G>T p.S582I | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100036697; called by muse, mutect2
- TTLL5 | c.628T>A p.Y210N | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs998794256, COSV99709833; called by muse, mutect2
- TTLL6 | c.1798G>A p.D600N (on ENST00000393382 / NM_001130918.3; = p.D293N on NM_173623.3) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV100938254; called by muse, mutect2
- TTN | c.22468C>A p.L7490I (on ENST00000591111; = p.L6563I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/69 reads (9%) | PolyPhen benign (0.011); catalogued as COSV100635402; called by muse, mutect2
- TTN | c.11407C>A p.Q3803K (on ENST00000591111; = p.Q3757K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/135 reads (10%) | catalogued as COSV100635405; called by muse, mutect2, varscan2
- UBE3A | c.1820A>T p.E607V | Missense Mutation (SNP) | VAF 32/287 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99218055; called by muse, mutect2, varscan2
- UGT2B4 | c.1234G>A p.A412T | Missense Mutation (SNP) | VAF 26/227 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs760393208, COSV100522784; called by muse, mutect2, varscan2
- UNC45B | c.1556G>A p.C519Y | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99269401; called by muse, mutect2, varscan2
- USP25 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs944126716, COSV99584844; called by muse, mutect2
- VGLL1 | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101034757, COSV65703863; called by muse, mutect2, varscan2
- WASF1 | c.280G>A p.D94N | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99661584; called by muse, mutect2
- WDR44 | c.1738-1G>T p.X580_splice | Splice Site (SNP) | VAF 21/209 reads (10%) | catalogued as COSV99562060; called by muse, mutect2, varscan2
- WWC3 | c.556G>T p.D186Y | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101081980, COSV99063125; called by muse, mutect2
- XDH | c.2763G>T p.M921I | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as COSV101052514; called by muse, mutect2
- ZFHX4 | c.7115C>G p.A2372G | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.022); catalogued as COSV99269081; called by muse, mutect2, varscan2
- ZFHX4 | c.8455G>C p.G2819R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99269086; called by muse, mutect2, varscan2
- ZNF142 | c.2182C>T p.Q728* (on ENST00000411696 / NM_001379660.1; = p.Q528* on NM_001105537.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 7/78 reads (9%) | catalogued as COSV101377020; called by muse, mutect2
- ZNF365 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV101238008; called by muse, mutect2
- ZNF449 | c.1121C>A p.T374K | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100203101; called by muse, mutect2, varscan2
- ZNF519 | c.1013A>G p.H338R | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV101645601; called by muse, mutect2, varscan2
- ZNF615 | c.124A>T p.S42C | Missense Mutation (SNP) | VAF 22/229 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs541814403, COSV100944041; called by muse, mutect2
- ZNF711 | c.1465G>A p.G489R | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV52156388; called by muse, mutect2
- ZNF761 | c.1801A>T p.T601S | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.15); catalogued as rs747274743, COSV100483530, COSV61888015; called by muse, mutect2
- ZUP1 | c.560-2A>C p.X187_splice | Splice Site (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100885168; called by muse, mutect2
- ALDH18A1 | c.26G>C p.G9A | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.196); called by muse, mutect2
- ARHGAP35 | c.3293_3296del p.R1098Mfs*45 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel
- ASPM | c.4498dup p.C1500Lfs*9 | Frame Shift Ins (INS) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- BOD1L1 | c.3898del p.V1300* | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- CFAP61 | c.1425del p.G476Vfs*11 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | called by mutect2, pindel, varscan2
- IGKV1-17 | c.294C>G p.S98R | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.393); called by muse, mutect2
- LRP2 | c.7489G>T p.G2497W | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAGEA4 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR9G4 | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.037); called by muse, mutect2
- PRAMEF14 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 46/445 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.466); called by muse, mutect2
- RHBDF2 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2
- SSU72P8 | c.328A>C p.T110P | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB48 | c.1496del p.G499Afs*39 | Frame Shift Del (DEL) | VAF 7/58 reads (12%) | called by mutect2, pindel, varscan2
- ADAMTS4 | c.699C>T p.F233= | Silent (SNP) | VAF 25/289 reads (9%) | catalogued as COSV100917608; called by muse, mutect2
- ALOX12B | c.1260C>T p.C420= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs1411540801, COSV100047877; called by muse, mutect2
- ANKRD30A | c.714A>G p.G238= (on ENST00000611781; = p.G182= on NM_052997.2) | Silent (SNP) | VAF 29/301 reads (10%) | catalogued as COSV100653607, COSV100654635; called by muse, mutect2, varscan2
- ATP7A | c.3555G>T p.R1185= | Silent (SNP) | VAF 20/278 reads (7%) | catalogued as COSV100431938; called by muse, mutect2
- ATRNL1 | c.2532T>C p.S844= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV100373231; called by muse, mutect2, varscan2
- BLK | c.657C>T p.P219= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as COSV99377787; called by muse, mutect2, varscan2
- BRINP3 | c.183A>T p.T61= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100819614; called by muse, mutect2, varscan2
- CASK | c.183G>T p.R61= | Silent (SNP) | VAF 11/158 reads (7%) | catalogued as COSV100587889; called by muse, mutect2
- CDKL5 | c.798G>A p.L266= | Silent (SNP) | VAF 17/148 reads (11%) | catalogued as COSV101184513; called by muse, mutect2, varscan2
- CECR2 | c.852C>T p.C284= (on ENST00000342247 / NM_001290047.2; = p.C121= on NM_001290046.1) | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs1220027305, COSV99379401; called by muse, mutect2, varscan2
- CLSTN2 | c.1179G>C p.V393= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV101515951, COSV71726139; called by muse, mutect2, varscan2
- CNTNAP5 | c.1764G>A p.E588= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV101444382; called by muse, mutect2, varscan2
- COQ3 | c.1020C>T p.A340= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as COSV99633114; called by muse, mutect2, varscan2
- CRISPLD2 | c.804G>A p.R268= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1361284987, COSV99296183; called by muse, mutect2, varscan2
- CSAG1 | c.51T>A p.A17= | Silent (SNP) | VAF 22/248 reads (9%) | catalogued as rs375328635, COSV100767529; called by muse, mutect2
- CYP4F8 | c.1188T>A p.P396= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100358285; called by muse, mutect2, varscan2
- EDNRB | c.1125A>G p.P375= (on ENST00000377211 / NM_001201397.1; = p.P285= on NM_000115.5) | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as COSV100527208; called by muse, mutect2, varscan2
- EEF1A2 | c.915C>A p.G305= | Silent (SNP) | VAF 17/122 reads (14%) | catalogued as COSV99420071; called by muse, mutect2, varscan2
- EPYC | c.312A>T p.T104= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99664962; called by muse, mutect2, varscan2
- ESRRG | c.816C>A p.A272= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV100754074; called by muse, mutect2
- FAM135B | c.3825G>C p.G1275= | Silent (SNP) | VAF 18/112 reads (16%) | catalogued as COSV52728640, COSV99428656; called by muse, mutect2, varscan2
- FBN1 | c.3015G>A p.E1005= | Silent (SNP) | VAF 9/125 reads (7%) | catalogued as rs1430562775, COSV100356646; called by muse, mutect2
- GCFC2 | c.822A>G p.Q274= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100319767; called by muse, mutect2
- GPC4 | c.348A>C p.A116= | Silent (SNP) | VAF 30/373 reads (8%) | catalogued as COSV100895631; called by muse, mutect2
- HECTD1 | c.4047T>G p.V1349= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV101237579; called by muse, mutect2, varscan2
- HLA-DQA1 | c.375G>T p.L125= | Silent (SNP) | VAF 10/97 reads (10%) | catalogued as COSV100568421; called by muse, mutect2
- IGSF1 | c.3135C>A p.T1045= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV100812459; called by muse, mutect2
- ITIH6 | c.1809A>T p.T603= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99514177; called by muse, mutect2
- LHCGR | c.1752T>C p.P584= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs377665383; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- MAGEA11 | c.666A>G p.L222= | Silent (SNP) | VAF 12/178 reads (7%) | catalogued as COSV100290767; called by muse, mutect2
- MAGEA4 | c.213C>T p.A71= | Silent (SNP) | VAF 16/167 reads (10%) | catalogued as COSV99367771; called by muse, mutect2
- MAGEC1 | c.1212C>A p.P404= | Silent (SNP) | VAF 36/319 reads (11%) | catalogued as COSV53582214; called by muse, varscan2
- MOSPD2 | c.1305G>A p.V435= | Silent (SNP) | VAF 13/237 reads (5%) | catalogued as COSV100996970; called by muse, mutect2
- MUC16 | c.25689C>A p.S8563= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV101202189; called by muse, mutect2, varscan2
- MUC16 | c.21714A>G p.K7238= | Silent (SNP) | VAF 23/209 reads (11%) | catalogued as rs923276750, COSV101202190; called by muse, mutect2, varscan2
- MYH7 | c.5409C>A p.I1803= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100806849, COSV62517323; called by muse, mutect2, varscan2
- MYO5C | c.2292A>G p.Q764= | Silent (SNP) | VAF 11/102 reads (11%) | catalogued as COSV99955823; called by muse, mutect2, varscan2
- NRDE2 | c.2508A>G p.P836= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV62964499; called by muse, mutect2
- OR2A12 | c.741G>A p.V247= | Silent (SNP) | VAF 18/238 reads (8%) | catalogued as COSV68821847; called by muse, mutect2
- OR5C1 | c.732C>T p.T244= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs532966704, COSV101030530; called by muse, mutect2, varscan2
- OR5I1 | c.84C>G p.V28= | Silent (SNP) | VAF 5/71 reads (7%) | catalogued as rs1244360529, COSV100041760; called by muse, mutect2
- OR9Q1 | c.150C>T p.L50= | Silent (SNP) | VAF 24/250 reads (10%) | catalogued as rs773218353, COSV59037042; called by muse, mutect2
- PAPPA2 | c.4467C>T p.C1489= | Silent (SNP) | VAF 16/153 reads (10%) | catalogued as COSV100868813; called by muse, mutect2, varscan2
- PCDHA3 | c.1761G>T p.A587= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100793851, COSV63543015; called by muse, mutect2, varscan2
- PCDHB12 | c.186G>T p.R62= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as rs782078462, COSV53400932, COSV99508002; called by muse, mutect2, varscan2
- PCDHGA8 | c.1488G>T p.L496= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99549347; called by muse, mutect2, varscan2
- PER2 | c.3564C>T p.R1188= | Silent (SNP) | VAF 21/236 reads (9%) | catalogued as rs537316218, COSV99612755; called by muse, mutect2
- PKN3 | c.1425A>G p.K475= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as rs970869837, COSV99404050; called by muse, mutect2
- PLCXD3 | c.780G>T p.V260= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100126618; called by muse, mutect2
- PLPPR5 | c.327T>C p.C109= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1017018121, COSV99588022; called by muse, mutect2
- PLXNB3 | c.186C>T p.G62= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV100738054; called by muse, mutect2
- PTGER4 | c.360C>T p.A120= | Silent (SNP) | VAF 27/251 reads (11%) | catalogued as COSV100201795; called by muse, mutect2, varscan2
- PTPRD | c.3138C>A p.S1046= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100647709; called by muse, mutect2, varscan2
- RELL2 | c.555T>C p.D185= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV99781586; called by muse, mutect2, varscan2
- ROS1 | c.6756T>C p.C2252= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1200820127, COSV100877860; called by muse, mutect2, varscan2
- RPL3 | c.129C>A p.L43= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV99335362; called by muse, mutect2
- RPP30 | c.522C>A p.L174= | Silent (SNP) | VAF 28/218 reads (13%) | catalogued as COSV99521077; called by muse, mutect2, varscan2
- SAMD3 | c.1227C>A p.L409= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100696360; called by mutect2, varscan2
- SCN3A | c.921T>C p.N307= | Silent (SNP) | VAF 6/99 reads (6%) | catalogued as COSV99328953; called by muse, mutect2
- SERPINB13 | c.738G>T p.V246= | Silent (SNP) | VAF 15/148 reads (10%) | catalogued as COSV99501346; called by muse, mutect2, varscan2
- SETBP1 | c.3426G>C p.L1142= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs540433821, COSV99955435; called by muse, mutect2, varscan2
- SLC35F1 | c.195C>A p.A65= | Silent (SNP) | VAF 17/151 reads (11%) | catalogued as COSV100838311, COSV64502496; called by muse, mutect2
- SLC37A1 | c.879A>T p.S293= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV100721764, COSV100721873; called by mutect2, varscan2
- SPEF2 | c.3168G>A p.V1056= | Silent (SNP) | VAF 16/150 reads (11%) | catalogued as COSV100609245; called by muse, mutect2, varscan2
- SRGAP3 | c.1695G>A p.V565= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV100841524; called by muse, mutect2, varscan2
- SSR4 | c.126C>A p.V42= | Silent (SNP) | VAF 16/131 reads (12%) | catalogued as COSV99473494; called by muse, mutect2, varscan2
- STRN3 | c.1845A>T p.P615= (on ENST00000357479 / NM_001083893.2; = p.P531= on NM_014574.4) | Silent (SNP) | VAF 9/108 reads (8%) | catalogued as COSV100671147; called by muse, mutect2
- SUPT6H | c.1179A>G p.L393= | Silent (SNP) | VAF 9/82 reads (11%) | catalogued as rs781700686, COSV100112903; called by muse, mutect2, varscan2
- TBATA | c.495G>A p.L165= | Silent (SNP) | VAF 23/212 reads (11%) | catalogued as COSV100165561; called by muse, mutect2, varscan2
- TCF20 | c.3135G>T p.R1045= | Silent (SNP) | VAF 6/77 reads (8%) | catalogued as COSV100167093; called by muse, mutect2
- TINAGL1 | c.303G>C p.P101= | Silent (SNP) | VAF 20/128 reads (16%) | catalogued as COSV99593139; called by muse, mutect2, varscan2
- TTN | c.36366A>T p.G12122= (on ENST00000591111; = p.G4698= on NM_003319.4) | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100620375; called by muse, mutect2, varscan2
- UAP1 | c.1554G>T p.V518= (on ENST00000271469 / NM_001324116.1; = p.V501= on NM_003115.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99618178; called by muse, mutect2
- UBE2NL | c.153G>T p.G51= | Silent (SNP) | VAF 18/161 reads (11%) | called by muse, mutect2, varscan2
- UNC45A | c.718C>A p.R240= | Silent (SNP) | VAF 29/166 reads (17%) | catalogued as COSV101266116, COSV67817741; called by muse, mutect2, varscan2
- USP29 | c.1671T>A p.V557= | Silent (SNP) | VAF 25/220 reads (11%) | catalogued as COSV99518873; called by muse, mutect2, varscan2
- ZNF235 | c.81T>C p.S27= | Silent (SNP) | VAF 30/264 reads (11%) | catalogued as COSV99349813; called by muse, mutect2, varscan2
- AC244258.1 | n.357C>A | RNA (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- ARPP19P1 | n.280A>G | RNA (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2, varscan2
- EMC3-AS1 | chr3:10008453 C>G | 3'Flank (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- HMGN2P46 | n.974G>T | RNA (SNP) | VAF 11/50 reads (22%) | called by muse, mutect2, varscan2
- MRPL43 | c.529-2151T>C | Intron (SNP) | VAF 8/116 reads (7%) | catalogued as COSV99273376; called by muse, mutect2
- SND1 | c.1779+6733C>G | Intron (SNP) | VAF 9/257 reads (4%) | catalogued as COSV100691311; called by muse, mutect2
- SNORD115-29 | n.36G>C | RNA (SNP) | VAF 42/466 reads (9%) | called by muse, mutect2
- SYTL2 | c.1615+1271G>T | Intron (SNP) | VAF 10/194 reads (5%) | called by muse, mutect2
- TNIK | c.2406+457A>T | Intron (SNP) | VAF 20/155 reads (13%) | catalogued as COSV99460394; called by muse, mutect2, varscan2
